Surgical pathology report (de-identified scan), TCGA case TCGA-56-A49D, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A49D-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Final Report

Patient

Location

Final Diagnosis

Left lung, pneumonectomy with frozen section:

Squamous cell carcinoma, non-keratinizing.

Grade: Moderately-differentiated.

Specimen Integrity: Intact.

Tumor site: Left upper lobe.

Tumor size: 4.4 cm in greatest dimension.

Tumor focality: Unifocal.

Tumor extension: Tumor invades the inked visceral pleural surface (PL2).

Margins: The bronchovascular surgical margins are negative for tumor.

Lymph nodes: One (1) of four (4) perihilar lymph nodes is involved by metastatic carcinoma.

AJCC Pathologic stage: pT2a pN2.

Level 9 lymph nodes:

Four (4) lymph nodes are identified.

No tumor is present.

AP window lymph node:

One (1) lymph node is identified, and is positive for metastatic carcinoma.

Left lung lymph node:

Three (3) lymph nodes are identified.

No tumor is present.

ICD-O-3

CPCF: carcinoma, squamous cell, NOS
8070/3

Path: carcinoma, squamous cell,
non-keratinizing, NOS

8072/3

Site: lung, upper lobe

C34.1

9-7-12
RD

Clinical Information

Left lung squamous cell carcinoma.

Frozen Section Diagnosis

Time in: Time out:

History: Squamous cell carcinoma of left lung upper lobe. Left lung pneumonectomy.

Gross: Neoplasm identified and comes very close to visceral pleura. Sample submitted to Expo research project. Bronchial vascular margin submitted for FS.

FS: Bronchial vascular margin is negative for tumor.

[page 2 of 2]
Surgical Pathology Final Report

T
C
C

Ordered by:

Location:

Gross Description

"NFSA." Received after frozen section is a 460 gram, 22.7 x 19.2 x 5.8 cm left lung. The bronchial and vascular margins have been previously sampled. The upper lobe has been previously sectioned to reveal a 4.4 x 4.2 cm white-tan firm mass. The mass grossly appears to abut the overlying pleura. The pleura overlying the mass will be inked black. No other masses or lesions are grossly identified in the remainder of the lung. The hilum of the lung is examined and there are 4 possible lymph nodes ranging from 0.3 to 1.5 cm. All lymph nodes will be sampled. A portion of the specimen has been submitted for frozen section in cassette "FSA,". "A1-A3," random sections of mass; "A4," random sections of uninvolved lung parenchyma; "A5," random sections of hilar nodes.

"B, Left lung level 9 lymph nodes." Received are 4 lymph nodes ranging from 0.6 to 2.5 cm. "B," all.

"C, Left lung level 5 AP window lymph node." Received is a 1.8 x 1.4 x 0.6 cm lymph node. The specimen will be bisected and submitted in toto. "C," all.

"D, Left lung lymph node." Received are 3 lymph nodes ranging from 0.5 to 1.0 cm. Also received is a 1.0 cm yellow-tan soft tissue fragment. The specimen will be submitted in toto. "D," all.

Performing Lab

Testing performed at

Reviewed (initials):	8/30/12	

8/30/12

Source: NCI Genomic Data Commons file 9df1eec9-58fb-4ecf-bb6a-87f4a000e0ff (TCGA-56-A49D.C80AAD15-0A9A-4A15-B757-1292352964FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).